RC case RC-B65O — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/27caa59f-dcbd-4594-9cfb-968dd5c64248

Demographics
Sex at birth: female; Race: black or african american; Country of residence at enrollment: United States; Year of birth: 1946; Vital status: Dead; Days to death: 192 days; Year of death: 2012.

Diagnoses (2)
1. Prolymphocytic leukemia, T-cell type (the primary disease): ICD-O-3 morphology code: 9834/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 65.5 years (23,927 days); Year of diagnosis: 2011; Method of diagnosis: Blood Draw; Ann Arbor B symptoms: Yes; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Ann arbor b symptoms described array: Night Sweats; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High Risk; Sites of involvement: Lymph Node, Axillary / Lymph Node, Mediastinal / Bone marrow / Peripheral blood / Spleen.
   Pathology details: Bone marrow malignant cells: Yes; Greatest tumor dimension: 2.6 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab; Initial disease status: Initial Diagnosis; Days to treatment start: 31 days; Days to treatment end: 34 days; Treatment outcome: Treatment Stopped Due to Toxicity; Reason treatment ended: Adverse Event; Timepoint category: First Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Pentostatin; Initial disease status: Initial Diagnosis; Days to treatment start: 69 days; Days to treatment end: 189 days; Treatment outcome: Partial Response; Reason treatment ended: Death; Timepoint category: Post Initial Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Treatment Stopped Due to Toxicity; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Prior malignancy of the colon (histology not recorded by GDC). Age at diagnosis: 57.5 years (21,020 days); Year of diagnosis: 2003; Days to diagnosis: -2,907 days (-8.0 years); AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -2,885 days (-7.9 years); Treatment anatomic sites: Colon.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 90.
- Day 192 (end of treatment course 1): Disease response: With Tumor.

Molecular and laboratory tests
- Lactate Dehydrogenase 434 U/L [Blood test normal range upper: 246].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Anemia / Hypertension.
- Timepoint category: Prior to Diagnosis; Risk factors: Skin Rash.
- Timepoint category: Initial Diagnosis; Weight: 91.2 kg; Height: 157 cm; BMI: 37.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (2 samples)
- Sample RC-B65O-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B65O-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
